Gene-level copy-number profile of tumor specimen CUPP-B4JI-TTM1-A from CCG case CUPP-B4JI, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage IV; Age at diagnosis: 72.5 years (26,485 days).
Specimen CUPP-B4JI-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e5575339-d60a-4d61-9ca4-746e12d55ef4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B4JI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,773 have no estimate.
https://portal.gdc.cancer.gov/files/49df3e48-63d5-4e67-b406-9e44e00258b1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 17,330; copy number 2: 35,052; copy number 3: 3,908; copy number 4: 2,075; copy number 5: 389; copy number 10: 7; copy number 11: 3; copy number 14: 3; copy number 16: 2; copy number 17: 14; copy number 19: 30; copy number 22: 25.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–53,312, 1 gene: OR4G4P.
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–1): RPS3AP15.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr15:21,010,494–21,015,078, 4 genes: IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 473 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,500,512, 7 genes, copy number 5: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr1:212,726,153–212,899,363, 8 genes, copy number 5: NSL1, TATDN3, AC104333.3, SPATA45, FLVCR1-DT, AC104333.1, AC104333.2, FLVCR1.
- chr1:246,682,108–246,691,821, 2 genes, copy number 5: AL591848.2, AL591848.1.
- chr11:69,048,932–70,436,584, 41 genes, copy number 16–22: TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr12:5,226,196–6,635,960, 43 genes, copy number 10–19: LINC02443, AC006206.2, AC006206.1, AC007848.2, AC007848.1, NTF3, ANO2, AC137627.1, VWF, RN7SL69P, AC005845.1, CD9, Y_RNA, ATP5MFP5, PLEKHG6, TNFRSF1A, RN7SL391P, SCNN1A, LTBR, AC005840.2, AC005840.1, SRP14P1, CD27-AS1, CD27, TAPBPL, VAMP1, AC005840.4, AC005840.3, MRPL51, NCAPD2, SCARNA10, AC006064.5, AC006064.3, GAPDH, AC006064.4, IFFO1, AC006064.1, NOP2, AC006064.6, CHD4, AC006064.2, SCARNA11, LPAR5.
- chr18:45,034–15,330,282, 367 genes, copy number 5 (broad region; genes not listed).
- chr21:12,999,676–13,120,807, 5 genes, copy number 5: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 14,683. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
